Gene-level copy-number profile of tumor specimen C3N-03202-01 (profiled together with C3N-03202-02) from CPTAC case C3N-03202, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA2; Tumor grade: G2; Age at diagnosis: 68.3 years (24,932 days).
Specimen C3N-03202-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8574ccb5-f5cd-499c-ba5e-57da96a10b3e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03202-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/f3a7762d-88d6-4ba5-91fe-53e3a5713bd4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 128; copy number 1: 2,852; copy number 2: 53,872; copy number 3: 1,738; copy number 4: 315; copy number 5: 3; copy number 6: 5.

Homozygous deletions (total copy number 0; autosomes only): 127 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:105,672,308–106,481,706, 125 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–2): IGHVIII-47-1, IGHV3-48.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:53,413,504–53,487,134, 2 genes, copy number 6: AC108114.1, FST.
- chr14:25,647,304–26,143,305, 1 gene, copy number 5 (within-gene range 2–5): LINC02306.
- chr14:25,916,015–26,208,424, 2 genes, copy number 5: AL132633.1, CYB5AP5.
- chr14:29,390,074–29,500,460, 3 genes, copy number 6: AL158058.1, AL158058.2, RNU11-5P.

Autosomal genes at a single copy (total copy number 1): 7. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
